Somatic mutation profile of tumor specimen TARGET-10-PANWZG-09A (aliquot TARGET-10-PANWZG-09A-01D) from TARGET case TARGET-10-PANWZG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,585 days).
Specimen TARGET-10-PANWZG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7300311f-9272-4ca5-8fee-76c3dcb8cdd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWZG-10A (Blood Derived Normal), aliquot TARGET-10-PANWZG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bec1908-f7cd-4abd-9df2-21781bc62d0e

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WDFY4 | c.9088A>G p.I3030V | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1564543859; called by muse, mutect2, varscan2
- ACSM5 | c.421G>C p.V141L | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- DNAH14 | c.1103T>G p.L368W (on ENST00000445597; = p.L349W on NM_001145154.3) | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ITIH1 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MYB | c.291A>C p.K97N | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF385D | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- KIF21A | c.4596G>A p.V1532= (on ENST00000361418 / NM_001378440.1; = p.V1519= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs752259428, COSV100735456; called by muse, mutect2, varscan2
- KRTAP10-7 | c.141C>T p.C47= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs377470749; called by muse, mutect2, varscan2
- SLC25A48 | c.276C>T p.C92= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as rs368023667, COSV99192019; called by muse, mutect2, varscan2
- TYRO3 | c.2151G>A p.A717= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs769707482, COSV55482452; called by muse, mutect2, varscan2
- ZNF415 | c.136+573C>G | Intron (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
